Somatic mutation profile of tumor specimen TCGA-76-6286-01A (aliquot TCGA-76-6286-01A-11D-1845-08) from TCGA case TCGA-76-6286, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.7 years (22,173 days).
Specimen TCGA-76-6286-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73bfbe6a-80dd-4864-a824-6d3ff9604b57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6286-10A (Blood Derived Normal), aliquot TCGA-76-6286-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c18b9858-b318-4a68-bf8d-b517b1c0c40f

The open-access MAF lists 68 somatic variants for this specimen: 50 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 45, Silent 18, Nonsense Mutation 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 47/101 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772110575, COSV55879949, COSV56003293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 44/105 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.01); catalogued as COSV58227845; called by muse, mutect2, varscan2
- CARMIL1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199969829, COSV61513647; called by muse, mutect2, varscan2
- CDH4 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs761235649, COSV64642021; called by muse, mutect2, varscan2
- CNTLN | c.1456A>G p.I486V | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs765713422, COSV52066262; called by muse, mutect2, varscan2
- CNTNAP5 | c.2122C>A p.P708T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769500372, COSV101443367, COSV70472741; called by muse, mutect2, varscan2
- DYNC1H1 | c.4078C>T p.R1360* | Nonsense Mutation (SNP) | VAF 66/146 reads (45%) | catalogued as COSV64134332; called by muse, mutect2, varscan2
- EDAR | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755654853, CM138355, COSV51499914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EZH2 | c.363G>C p.M121I | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.546); catalogued as COSV57446539, COSV57461049; called by muse, mutect2, varscan2
- F2RL3 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs765271460, COSV50185124; called by muse, mutect2, varscan2
- FLNA | c.3718G>A p.V1240M | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61037442; called by muse, mutect2, varscan2
- GABRA6 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV50877559; called by muse, mutect2, varscan2
- GAMT | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs139890971, COSV52038309; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRB7 | c.939G>C p.K313N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100485479, COSV58446276; called by muse, mutect2, varscan2
- HRH3 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs142903103; called by muse, mutect2, varscan2
- KCND1 | c.1897G>A p.G633S | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV50233846; called by muse, mutect2, varscan2
- KRT25 | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV56443621; called by muse, mutect2, varscan2
- KRT86 | c.887G>A p.W296* | Nonsense Mutation (SNP) | VAF 40/94 reads (43%) | catalogued as COSV53291448; called by muse, mutect2, varscan2
- MPP4 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs753283774, COSV59628695; called by muse, mutect2, varscan2
- MUC17 | c.9617C>G p.T3206S | Missense Mutation (SNP) | VAF 47/856 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV60279938; called by muse, mutect2
- OR11H12 | c.461A>C p.H154P | Missense Mutation (SNP) | VAF 82/574 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs757442033, COSV73569072, COSV73569322; called by muse, varscan2
- OR5P2 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 29/65 reads (45%) | catalogued as rs747889508, COSV61489896; called by muse, mutect2, varscan2
- PCLO | c.6533C>A p.P2178H | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs764859401, COSV61616106, COSV61665149; called by muse, mutect2, varscan2
- PDZD3 | c.1451G>T p.C484F (on ENST00000531114; = p.C404F on NM_024791.4) | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV52701403; called by muse, mutect2, varscan2
- PTEN | c.812T>C p.F271S | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs142420551, COSV64289376; called by muse, mutect2, varscan2
- RASAL3 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52991230; called by muse, mutect2, varscan2
- RASGRP4 | c.772G>C p.V258L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372706430; called by muse, mutect2, varscan2
- RB1 | c.1004T>G p.L335* | Nonsense Mutation (SNP) | VAF 87/113 reads (77%) | catalogued as COSV57294419, COSV57296214; called by muse, mutect2, varscan2
- RIMBP2 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs778616977, COSV55464362; called by muse, mutect2, varscan2
- RIMS2 | c.1021C>T p.R341C (on ENST00000666250 / NM_001348490.2; = p.R149C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766129122, COSV51653199; called by muse, mutect2, varscan2
- RPE65 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52013194; called by muse, mutect2, varscan2
- SLC1A6 | c.1115C>G p.P372R | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as COSV55667859, COSV55673953, COSV55674425; called by muse, mutect2, varscan2
- SLC9C2 | c.1112G>C p.W371S | Missense Mutation (SNP) | VAF 81/248 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62943786, COSV62945541; called by muse, mutect2, varscan2
- STON1 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147440328, COSV100562377; called by muse, mutect2, varscan2
- TACR3 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs368975103, CM166113; called by muse, mutect2, varscan2
- TJP3 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs538012849, COSV53660823; called by muse, mutect2, varscan2
- TMC1 | c.1861G>A p.V621I | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52767505; called by muse, mutect2, varscan2
- TP53 | c.1123C>A p.Q375K | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV52716070, COSV52776099; called by muse, mutect2, varscan2
- TTC4 | c.1153C>G p.Q385E | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV64884358; called by muse, mutect2, varscan2
- USP26 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs764088622, CM164474, COSV63708038; called by muse, mutect2, varscan2
- VSIG4 | c.1003A>G p.R335G | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV66073135; called by muse, mutect2, varscan2
- YBX3 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 108/223 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as rs1032991280, COSV54384509; called by muse, mutect2, varscan2
- ZDHHC4 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781761812, COSV60105939; called by muse, mutect2, varscan2
- ZNF804A | c.126G>C p.K42N | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56435547; called by muse, mutect2, varscan2
- ZNF827 | c.2549G>A p.C850Y | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65224836; called by muse, mutect2, varscan2
- ZNF831 | c.2781A>C p.R927S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV64037333; called by muse, mutect2
- ZSCAN1 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs370250109; called by muse, mutect2, varscan2
- ZSWIM8 | c.3359G>A p.R1120H (on ENST00000605216 / NM_001242487.2; = p.R1125H on NM_015037.3) | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as rs1051407197, COSV55212556; called by muse, mutect2, varscan2
- MSL3 | c.1378_1381del p.F460* (on ENST00000312196 / NM_078629.4; = p.F294* on NM_006800.4) | Frame Shift Del (DEL) | VAF 49/59 reads (83%) | called by mutect2, pindel, varscan2
- AFF2 | c.1227C>A p.T409= | Silent (SNP) | VAF 46/52 reads (88%) | catalogued as COSV53976580; called by muse, mutect2, varscan2
- ASTN2 | c.1474T>C p.L492= (on ENST00000313400 / NM_001365069.1; = p.L441= on NM_014010.5) | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV57750993; called by muse, mutect2, varscan2
- CACNA2D2 | c.249C>T p.G83= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs371367882; ClinVar: uncertain significance; called by muse, mutect2
- EHD4 | c.1407C>T p.N469= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs201800565, COSV55003288; called by mutect2, varscan2
- FAM3B | c.495C>T p.N165= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs370045496, COSV63612787; called by muse, mutect2, varscan2
- FBXO10 | c.2598C>A p.I866= | Silent (SNP) | VAF 65/135 reads (48%) | catalogued as rs749967085, COSV52831357, COSV52831826; called by muse, mutect2, varscan2
- HEPHL1 | c.1575C>T p.S525= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs61746203; called by muse, mutect2, varscan2
- KRTAP13-1 | c.273C>T p.P91= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as rs747708391, COSV100819852, COSV62662826; called by muse, mutect2, varscan2
- MAP3K11 | c.1200G>A p.K400= | Silent (SNP) | VAF 41/55 reads (75%) | catalogued as rs781768921, COSV58418274; called by muse, mutect2, varscan2
- MRPS7 | c.330C>T p.L110= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs376298524; called by muse, mutect2, varscan2
- NXN | c.957C>T p.N319= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs777784278, COSV61093924; called by muse, mutect2, varscan2
- PF4V1 | c.198C>T p.A66= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs147144357; called by muse, mutect2, varscan2
- POTEE | c.858A>G p.Q286= | Silent (SNP) | VAF 49/272 reads (18%) | catalogued as COSV58224277; called by muse, mutect2, varscan2
- RPRD2 | c.1569T>A p.S523= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV64818665; called by muse, mutect2, varscan2
- RYR2 | c.6279C>T p.D2093= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs771328006, COSV63661917; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHISA5 | c.273G>A p.S91= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs369971951, COSV56498745; called by muse, mutect2, varscan2
- SLCO5A1 | c.1533T>C p.S511= | Silent (SNP) | VAF 47/107 reads (44%) | catalogued as COSV52653645; called by muse, mutect2, varscan2
- TTC7A | c.723A>G p.E241= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV55408410; called by mutect2, varscan2
